Somatic mutation profile of tumor specimen TCGA-TQ-A7RK-02A (aliquot TCGA-TQ-A7RK-02A-11D-A36O-08) from TCGA case TCGA-TQ-A7RK, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.4 years (10,742 days).
Specimen TCGA-TQ-A7RK-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a006eebc-25cb-44cf-ad70-eab57fe8bf7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RK-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RK-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0899395-91b6-4128-bc73-6cc75a259039

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Frame Shift Del 3, Silent 3, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 32/75 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 38/48 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.16940T>A p.V5647E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as CD122148, COSV101316058; called by mutect2, varscan2
- ATRX | c.4291C>T p.Q1431* | Nonsense Mutation (SNP) | VAF 29/40 reads (73%) | catalogued as COSV100970319; called by muse, mutect2, varscan2
- C2orf16 | c.5179C>T p.R1727C | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.731); catalogued as rs745938050, COSV100820671, COSV62676703; called by muse, mutect2, varscan2
- C4orf19 | c.932A>C p.D311A | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99448466; called by muse, mutect2, varscan2
- CPAMD8 | c.3511G>A p.G1171R (on ENST00000651564; = p.G1124R on NM_015692.5) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760356652, COSV101488444; called by muse, mutect2, varscan2
- ECT2L | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV100871984; called by muse, mutect2, varscan2
- FBLN1 | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs775219455, COSV99410670; called by muse, mutect2, varscan2
- G2E3 | c.1072A>T p.K358* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs778769231, COSV52840527; called by muse, mutect2, varscan2
- GPER1 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99866836; called by muse, mutect2, varscan2
- MUC16 | c.15320C>G p.T5107S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as COSV101200048, COSV67500637; called by muse, mutect2, varscan2
- OR4A5 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100157005; called by muse, mutect2, varscan2
- POLR1E | c.1087G>A p.G363R (on ENST00000377792 / NM_001282766.1; = p.G301R on NM_022490.4) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV66772217; called by muse, mutect2, varscan2
- SLC1A6 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs896326116, COSV55674395; called by muse, mutect2, varscan2
- SUMF1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs1249221556, COSV55994224; called by muse, mutect2, varscan2
- USH2A | c.8021C>T p.T2674I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV100235809; called by muse, varscan2
- VCAN | c.2957T>C p.L986S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV99425999; called by muse, mutect2
- ZNFX1 | c.3254C>A p.P1085H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147830129; called by mutect2, varscan2
- IGHG1 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RFTN1 | c.928_931del p.T310* | Frame Shift Del (DEL) | VAF 31/173 reads (18%) | called by mutect2, pindel, varscan2
- ROCK1 | c.1723_1726del p.I575Vfs*3 | Frame Shift Del (DEL) | VAF 9/101 reads (9%) | called by mutect2, pindel
- WFIKKN2 | c.560del p.P187Hfs*41 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- ABCC9 | c.213G>T p.L71= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV99685829; called by muse, mutect2
- COL5A1 | c.363C>T p.N121= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs369180922; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR5T1 | c.600T>C p.S200= | Silent (SNP) | VAF 72/175 reads (41%) | catalogued as COSV100478902, COSV57301674, COSV57301917; called by muse, mutect2, varscan2
- LEKR1 | c.*852T>C | 3'UTR (SNP) | VAF 22/44 reads (50%) | catalogued as rs1170930370, COSV100738731; called by muse, mutect2, varscan2
